CMI case ASCProject_0194 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/e14774bf-262b-4f07-851b-7f7118ddefb1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Heart; Site of resection or biopsy: Heart; Age at diagnosis: 32.3 years (11,785 days).

Biospecimens (2 samples)
- Sample ASCProject_0194_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Sample ASCProject_0194_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Heart; Preservation method: FFPE.
